TCGA case TCGA-UW-A72T — Kidney Chromophobe (TCGA-KICH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: University of North Carolina. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d3210869-e2f3-4429-ba46-ceeaa21de943

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 57 years; Vital status: Alive.

Diagnoses (2)
1. Renal cell carcinoma, chromophobe type (the primary disease): ICD-O-3 morphology code: 8317/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 57.5 years (20,985 days); Year of diagnosis: 2013; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T3a; AJCC pathologic N: NX; AJCC pathologic stage: Stage III; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 387 days (1.1 years).
   Pathology details: Consistent pathology review: Yes; Sarcomatoid present: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Hodgkin lymphoma, NOS: ICD-O-3 morphology code: 9650/3; Tissue or organ of origin: Thorax, NOS; Classification of tumor: Prior primary.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Chest Wall / Rib.
   Recorded as not given: Pharmaceutical Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 114 days; Disease response: Tumor Free.
- Days to follow up: 387 days (1.1 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Calcium: Normal.
- Platelets: Normal.
- Leukocytes: Normal.
- Hemoglobin: Normal.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-UW-A72T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 620 mg.
  Slide TCGA-UW-A72T-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
- Sample TCGA-UW-A72T-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-UW-A72T-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Sarcomatoid features: No; Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Lymph nodes examined: No; Tumor status: Tumor free; Tobacco smoking history indicator: 1; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: Yes; Tumor status: Tumor free.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Chest wall; Other malignancy histological type: Hodgkin's Lymphoma.
- Other malignancy form, Surgery: Other malignancy surgery type: Resxn of chest wall mass along with 3 ribs.
- Other malignancy form, Radiation treatment: Radiation therapy extent: Locoregional; History radiation treatment to site of TCGA tumor: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 387 days; disease-specific survival: no event (censored), 387 days; disease-free interval: no event (censored), 387 days; progression-free interval: no event (censored), 387 days.
